Gene-level copy-number profile of tumor specimen TCGA-77-8133-01A from TCGA case TCGA-77-8133, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.3 years (27,139 days).
Specimen TCGA-77-8133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2cc832d3-ca6b-4ae4-b554-8bad6ee13e63.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8133-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8caa658-8741-4909-9248-6b60a90dcc85

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 96; copy number 2: 21,300; copy number 3: 22,133; copy number 4: 13,116; copy number 5: 1,202; copy number 6: 1,018; copy number 7: 74; copy number 8: 56; copy number 9: 384; copy number 10: 104; copy number 12: 92; copy number 14: 49; copy number 15: 47; copy number 23: 16; copy number 32: 63; copy number 34: 48; copy number 41: 10; copy number 62: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8133-01A-12D-2243-01): tumor purity 0.4, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 946 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,083,499–198,222,513, 588 genes, copy number 8–34 (within-gene range 5–34) (broad region; genes not listed).
- chr7:54,621,025–57,425,676, 126 genes, copy number 7–62 (broad region; genes not listed).
- chr11:68,612,899–71,863,658, 96 genes, copy number 8–32 (broad region; genes not listed).
- chr11:71,878,453–71,884,561, 1 gene, copy number 15: DEFB131B.
- chr13:72,453,902–78,659,155, 92 genes, copy number 9 (broad region; genes not listed).
- chr14:48,819,360–49,901,950, 32 genes, copy number 10: AL512360.1, AL110505.1, ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P.
- chr20:10,637,684–11,345,855, 11 genes, copy number 10–14 (within-gene range 6–14): JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
